Gene-level copy-number profile of specimen HCM-SANG-1299-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1299-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 19503b06-090f-4640-90c2-ffeb1bfcbbe0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1299-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/3fb6b738-1227-4169-81f3-8f8bccf2fc06

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 711; copy number 2: 18,168; copy number 3: 22,846; copy number 4: 15,635; copy number 5: 186; copy number 6: 509; copy number 7: 1; copy number 8: 34; copy number 9: 43; copy number 10: 86; copy number 11: 44; copy number 12: 8; copy number 13: 49; copy number 15: 2; copy number 16: 1; copy number 19: 1; copy number 20: 23; copy number 26: 6; copy number 40: 2; copy number 41: 1; copy number 62: 4; copy number 71: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 338 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:29,824,742–36,830,456, 207 genes, copy number 8–19 (broad region; genes not listed).
- chr9:65,219,987–65,230,861, 2 genes, copy number 8: AL512605.1, AL512605.2.
- chr11:45,355,371–46,594,125, 40 genes, copy number 40–71: LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1.
- chr14:55,559,072–58,551,297, 57 genes, copy number 7–9 (within-gene range 3–9): KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2, OTX2-AS1, AL161757.4, RN7SL461P, RNU6-1204P, AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1, AL355834.1, NAA30, CCDC198, SLC35F4, AL161804.1, AL136520.1, RN7SKP99, AL049838.1, ARMH4, AL121579.2, UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1.
- chr19:28,790,812–30,228,715, 32 genes, copy number 15–26 (within-gene range 6–26): MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.

Autosomal genes at a single copy (total copy number 1): 711. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
